Somatic mutation profile of tumor specimen 0DUKHD from CCDI case PBCLLK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 1.2 years (426 days).
Specimen 0DUKHD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48716505-bc71-41fa-a83f-d41e16688c10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUKIY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b896251b-34f9-4821-b3a1-290a99cc9ac3

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 2, 5'UTR 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBF1 | c.1627G>A p.V543I (on ENST00000586717; = p.V557I on NM_001319193.1) | Missense Mutation (SNP) | VAF 264/729 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs191601755; called by muse, mutect2, varscan2
- GLB1L3 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 495/1251 reads (40%) | catalogued as rs753110925; called by muse, mutect2, varscan2
- GRIP1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 684/1546 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1406416797, COSV54032398; called by muse, mutect2, varscan2
- LRRK2 | c.6422C>T p.T2141M | Missense Mutation (SNP) | VAF 135/1400 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs111691891, CM081687, COSV54149375; ClinVar: uncertain significance; called by muse, mutect2
- TTF1 | c.821dup p.S275Vfs*2 | Frame Shift Ins (INS) | VAF 197/505 reads (39%) | catalogued as rs770528448; called by mutect2, varscan2
- VARS1 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 101/759 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as rs770836689; called by muse, mutect2, varscan2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 28/870 reads (3%) | called by muse, mutect2
- DLG1 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 32/1072 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- SLC2A13 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 150/1079 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CELF5 | c.1152G>A p.Q384= | Silent (SNP) | VAF 128/748 reads (17%) | called by muse, mutect2, varscan2
- MAPK4 | c.507C>T p.F169= | Silent (SNP) | VAF 302/767 reads (39%) | catalogued as rs762000392, COSV68543795; called by muse, mutect2, varscan2
- RREB1 | c.2367C>T p.P789= | Silent (SNP) | VAF 92/700 reads (13%) | catalogued as rs763144707; called by muse, mutect2, varscan2
- AC107023.1 | chr12:40444198 A>G | 5'Flank (SNP) | VAF 60/1480 reads (4%) | catalogued as rs1224794233; called by muse, mutect2
- TRIM45 | c.-82C>A | 5'UTR (SNP) | VAF 115/249 reads (46%) | called by muse, mutect2, varscan2
